Somatic mutation profile of tumor specimen TCGA-GH-A9DA-01A (aliquot TCGA-GH-A9DA-01A-21D-A37N-09) from TCGA case TCGA-GH-A9DA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 27.8 years (10,160 days).
Specimen TCGA-GH-A9DA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 117571f9-e727-41a6-a6a6-a623674119c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GH-A9DA-10A (Blood Derived Normal), aliquot TCGA-GH-A9DA-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bf67786-690b-42bf-acc7-5c79a4864bd0

The open-access MAF lists 77 somatic variants for this specimen: 59 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 16, Nonsense Mutation 6, Splice Site 2, Frame Shift Del 1, Nonstop Mutation 1, 5'UTR 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA9 | c.4627G>T p.A1543S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV100382957; called by muse, mutect2, varscan2
- ADAMTS10 | c.2578G>T p.A860S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.293); catalogued as COSV99546750; called by muse, mutect2, varscan2
- ALMS1 | c.1484C>G p.S495* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as COSV100042003, COSV52520271; called by muse, mutect2, varscan2
- ARL10 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 37/74 reads (50%) | catalogued as rs771015954, COSV100119029; called by muse, mutect2, varscan2
- ATG2B | c.6236G>C p.*2079Sext*43 | Nonstop Mutation (SNP) | VAF 9/13 reads (69%) | catalogued as COSV99952015; called by muse, mutect2, varscan2
- ATR | c.4123G>A p.E1375K | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as COSV63383526; called by muse, varscan2
- B4GALT1 | c.1031C>G p.S344* | Nonsense Mutation (SNP) | VAF 26/64 reads (41%) | catalogued as COSV101122977; called by muse, mutect2, varscan2
- BAHD1 | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as rs777256504, COSV101346748; called by muse, mutect2, varscan2
- C2orf16 | c.3836G>A p.R1279K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV62674136, COSV62677485; called by muse, mutect2, varscan2
- CA11 | c.704T>C p.I235T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV99320584; called by muse, mutect2
- CCDC178 | c.2041G>A p.E681K (on ENST00000383096 / NM_001105528.3; = p.E643K on NM_198995.3) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV100284380, COSV55796493; called by muse, mutect2, varscan2
- CCDC66 | c.523G>C p.E175Q (on ENST00000394672 / NM_001353147.1; = p.E141Q on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as COSV100413862; called by muse, mutect2, varscan2
- CFAP251 | c.2092C>G p.H698D | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV99995981; called by muse, mutect2, varscan2
- COMMD9 | c.39G>C p.Q13H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); catalogued as COSV99661238; called by muse, mutect2, varscan2
- DAB2IP | c.133C>G p.Q45E (on ENST00000408936; = p.Q17E on NM_032552.3) | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (1); PolyPhen possibly damaging (0.585); catalogued as COSV99405184; called by muse, mutect2, varscan2
- DISP2 | c.3068C>G p.S1023C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51116463, COSV51141900; called by muse, mutect2, varscan2
- DISP2 | c.3578C>T p.S1193F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99139857; called by muse, mutect2, varscan2
- DOCK2 | c.4214-1G>A p.X1405_splice | Splice Site (SNP) | VAF 12/59 reads (20%) | catalogued as COSV99911511; called by muse, mutect2, varscan2
- EIF3E | c.52C>G p.L18V | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs201452382, COSV55202275; called by muse, mutect2, varscan2
- EPB41L3 | c.595G>C p.D199H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59454484; called by muse, mutect2, varscan2
- ETAA1 | c.799C>G p.Q267E | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV55474358, COSV99712691; called by muse, mutect2, varscan2
- FAT1 | c.3587T>A p.I1196N | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101499269; called by muse, varscan2
- FBXL19 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as COSV100608785; called by muse, mutect2, varscan2
- HNRNPK | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.505); catalogued as COSV100698950; called by muse, mutect2, varscan2
- HRNR | c.2907G>T p.R969S | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV100913300; called by muse, mutect2, varscan2
- ITGA9 | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.232); catalogued as COSV99292360; called by muse, mutect2, varscan2
- KCNB2 | c.1924G>C p.E642Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.328); catalogued as COSV101578735, COSV73050384; called by muse, mutect2, varscan2
- KRT10 | c.563C>G p.S188* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as COSV54091740; called by muse, mutect2, varscan2
- MAGEB16 | c.352G>C p.A118P | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.212); catalogued as COSV101303294, COSV67873820, COSV67874582; called by muse, mutect2
- MDN1 | c.10148G>A p.R3383Q | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.559); catalogued as rs763038013, COSV65517306; called by muse, mutect2, varscan2
- MLANA | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs142544535; called by muse, mutect2, varscan2
- MRE11 | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.129); catalogued as COSV100119564; called by muse, mutect2, varscan2
- MYO18B | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs765087033; called by muse, mutect2, varscan2
- NBPF26 | c.2485A>G p.T829A (on ENST00000620612; = p.T567A on NM_001351372.1) | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); catalogued as rs1352266118; called by muse, mutect2
- NCAN | c.3256G>T p.E1086* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as COSV99387011; called by muse, mutect2, varscan2
- NEXMIF | c.2423C>A p.P808H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV50121865, COSV99280381; called by muse, mutect2
- NF2 | c.115-1G>A p.X39_splice | Splice Site (SNP) | VAF 43/53 reads (81%) | catalogued as CS002891, COSV58521769, COSV58526337, COSV58528057; called by muse, mutect2, varscan2
- NPY5R | c.719G>A p.C240Y | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.149); catalogued as COSV100642738; called by muse, mutect2, varscan2
- NR2F2 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV101240990, COSV101241104; called by muse, mutect2, varscan2
- NUP88 | c.511C>G p.L171V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV56708022, COSV99851590, COSV99851942; called by muse, mutect2, varscan2
- NXPH1 | c.809C>G p.S270W | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs750253607, COSV101339654; called by muse, mutect2, varscan2
- OR7G1 | c.161A>G p.H54R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV99528507; called by muse, mutect2, varscan2
- PCDHA4 | c.2200C>T p.P734S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.031); catalogued as COSV100793313, COSV63545367; called by muse, mutect2, varscan2
- PCDHGA9 | c.1231G>C p.D411H | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99535512; called by muse, mutect2, varscan2
- PIK3R5 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as rs747280160, COSV99353171; called by muse, mutect2, varscan2
- PIP5K1A | c.835C>T p.P279S (on ENST00000368888 / NM_001135638.2; = p.P266S on NM_003557.3) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100576589; called by muse, mutect2, varscan2
- PTPN13 | c.6874G>A p.D2292N (on ENST00000411767 / NM_080683.3; = p.D2273N on NM_006264.3) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100364543; called by muse, mutect2, varscan2
- SIGLEC12 | c.656G>C p.R219P (on ENST00000291707 / NM_053003.4; = p.R101P on NM_033329.2) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52459930, COSV52462907, COSV99389213; called by muse, mutect2, varscan2
- ST7L | c.1347G>C p.W449C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768763547, COSV100573725; called by muse, mutect2, varscan2
- TTI1 | c.1832C>G p.S611* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as rs1339903602, COSV65062631; called by muse, mutect2, varscan2
- TTN | c.46930G>C p.E15644Q (on ENST00000591111; = p.E8220Q on NM_003319.4) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | PolyPhen benign (0.09); catalogued as COSV100605093, COSV60108261; called by muse, mutect2, varscan2
- TVP23A | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51594825; called by muse, mutect2, varscan2
- VARS1 | c.1481A>G p.E494G | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100989925; called by muse, mutect2, varscan2
- VPS13D | c.8412C>G p.I2804M | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99166097; called by muse, mutect2, varscan2
- WDR47 | c.1952T>C p.V651A (on ENST00000369962 / NM_001142551.2; = p.V652A on NM_014969.5) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100728300, COSV63060009; called by muse, mutect2, varscan2
- ZXDB | c.2209C>G p.L737V | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV100885808, COSV66492245; called by muse, mutect2
- BMPR1A | c.1538_1539del p.T513Sfs*5 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | called by pindel, varscan2
- HUWE1 | c.3096dup p.K1033* | Frame Shift Ins (INS) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- PPP1R9B | c.1526G>A p.S509N | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2
- BDP1 | c.27G>A p.V9= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100702929; called by muse, mutect2, varscan2
- CELA2B | c.267C>T p.N89= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV101025755; called by muse, mutect2, varscan2
- DDX51 | c.1026C>A p.I342= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV100223025; called by muse, mutect2, varscan2
- GRM8 | c.2391C>T p.F797= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV58802924; called by muse, mutect2, varscan2
- HBG1 | c.255C>T p.T85= | Silent (SNP) | VAF 4/34 reads (12%) | called by mutect2, varscan2
- HBG2 | c.255C>T p.T85= | Silent (SNP) | VAF 19/132 reads (14%) | catalogued as COSV100400612; called by muse, mutect2, varscan2
- KASH5 | c.1479G>C p.V493= | Silent (SNP) | VAF 35/74 reads (47%) | catalogued as COSV101483429; called by muse, mutect2, varscan2
- KRT16 | c.1377C>G p.L459= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100052909; called by muse, varscan2
- LEPROT | c.138C>T p.P46= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV100756513; called by muse, mutect2, varscan2
- MCRS1 | c.837G>C p.L279= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as COSV99235059; called by muse, mutect2, varscan2
- NBEAL2 | c.423C>T p.L141= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV52761287, COSV99435574; called by muse, mutect2, varscan2
- POLR2C | c.414C>T p.D138= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99538280; called by muse, mutect2, varscan2
- SAP130 | c.804C>T p.I268= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as COSV99384509; called by muse, mutect2, varscan2
- SETD2 | c.2722C>T p.L908= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs1256470239, COSV100338688, COSV57444471; called by muse, mutect2, varscan2
- SRRT | c.711C>T p.L237= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs1395854081, COSV100730057; called by muse, mutect2, varscan2
- TRPS1 | c.2676C>T p.S892= (on ENST00000220888 / NM_001330599.2; = p.S905= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs756383722, COSV55237032, COSV55239631; called by muse, mutect2, varscan2
- DENND10P1 | n.469T>A | RNA (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- ZNF688 | c.-610G>C | 5'UTR (SNP) | VAF 28/84 reads (33%) | catalogued as COSV99794175, COSV99794406; called by muse, mutect2, varscan2
